Gene-level copy-number profile of tumor specimen C3L-06124-01 from CPTAC case C3L-06124, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 67.1 years (24,503 days).
Specimen C3L-06124-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 50463268-9900-452c-bce4-63f13fe31b75.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06124-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/3d18e252-ca49-46a7-9d62-85d16954bea6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 399; copy number 2: 4,905; copy number 3: 23,457; copy number 4: 20,283; copy number 5: 4,239; copy number 6: 2,969; copy number 7: 202; copy number 8: 1,502; copy number 10: 63; copy number 13: 86; copy number 15: 88; copy number 17: 132; copy number 21: 55.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:166,918,364–166,918,478, 1 gene (within-gene range 0–1): RNA5SP171.
- chr5:59,039,761–59,063,503, 1 gene (within-gene range 0–2): AC092343.1.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:12,341,426–12,388,296, 5 genes: DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,128 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:184,387,029–197,935,478, 142 genes, copy number 7 (broad region; genes not listed).
- chr6:55,434,373–57,646,850, 24 genes, copy number 7: HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1.
- chr8:8,059,572–8,199,973, 1 gene, copy number 8 (within-gene range 0–8): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes, copy number 8: ENPP7P1, FAM85B, AC068020.1.
- chr8:46,028,804–89,415,071, 623 genes, copy number 8 (broad region; genes not listed).
- chr8:90,058,608–145,066,685, 863 genes, copy number 8 (broad region; genes not listed).
- chr9:60,914,407–61,789,426, 18 genes, copy number 7: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr18:9,020,029–9,402,420, 12 genes, copy number 8: RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3.
- chr18:20,946,906–23,956,222, 63 genes, copy number 10 (broad region; genes not listed).
- chr19:33,795,933–40,751,553, 361 genes, copy number 13–21 (within-gene range 3–21) (broad region; genes not listed).
- chr21:8,857,260–9,059,060, 6 genes, copy number 7: CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4.
- chr21:9,325,013–9,914,846, 12 genes, copy number 7: CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.

Autosomal genes at a single copy (total copy number 1): 399. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
